Somatic mutation profile of tumor specimen MP2PRT-PAUYUF-TMP1-A (aliquot MP2PRT-PAUYUF-TMP1-A-1-0-D-A819-36) from MP2PRT case MP2PRT-PAUYUF, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.1 years (2,955 days).
Specimen MP2PRT-PAUYUF-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 01343668-b45a-4649-967b-a26549cebf3a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUYUF-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUYUF-NB1-A-1-0-D-A819-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d0279622-8333-4d42-b6d2-86f88aae0df5

The open-access MAF lists 10 somatic variants for this specimen: 10 protein-altering or splice-affecting.
By variant classification: Missense Mutation 8, Frame Shift Ins 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 60/267 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- PTPN11 | c.227A>T p.E76V | Missense Mutation (SNP) | VAF 30/258 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs121918465, CM112765, CM1314032, CM137734, COSV61005372, COSV61006382, COSV61007426; ClinVar: pathogenic; called by muse, varscan2
- ABCA9 | c.4198G>A p.A1400T | Missense Mutation (SNP) | VAF 108/227 reads (48%) | SIFT tolerated (0.41); PolyPhen benign (0.055); catalogued as rs1386994010, COSV60623882; called by muse, varscan2
- GASK1B | c.1480G>A p.D494N | Missense Mutation (SNP) | VAF 99/234 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1350161602, COSV99647432; called by muse, varscan2
- KCNMA1 | c.3319G>A p.D1107N (on ENST00000286628 / NM_001161352.2; = p.D1049N on NM_002247.4) | Missense Mutation (SNP) | VAF 101/265 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.838); catalogued as rs1314238418, COSV54278061; called by muse, mutect2, varscan2
- SEC14L5 | c.856C>T p.R286C | Missense Mutation (SNP) | VAF 83/313 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200586557; called by muse, mutect2, varscan2
- AJUBA | c.835_836insGTGGACG p.E279Gfs*29 | Frame Shift Ins (INS) | VAF 162/578 reads (28%) | called by mutect2, varscan2
- CAPN11 | c.2046G>T p.Q682H | Missense Mutation (SNP) | VAF 90/233 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- ERG | c.841_842insCGGCCC p.A280_Q281insPA (on ENST00000398919 / NM_001243428.1; = p.A256_Q257insPA on NM_004449.4) | In Frame Ins (INS) | VAF 46/232 reads (20%) | called by mutect2, pindel, varscan2
- GABPA | c.163C>A p.L55I | Missense Mutation (SNP) | VAF 71/284 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
